Somatic mutation profile of tumor specimen HCM-CSHL-0092-C25-01A (aliquot HCM-CSHL-0092-C25-01A-21D-A786-36) from HCMI case HCM-CSHL-0092-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 69.3 years (25,328 days).
Specimen HCM-CSHL-0092-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9a5f968-82e9-4e09-9ec9-a8e98ae26c0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0092-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-0092-C25-11A-11D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebb5c8ae-e5a2-4534-9c8c-b610a63e97d5

The open-access MAF lists 86 somatic variants for this specimen: 52 protein-altering or splice-affecting, 24 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 24, Intron 6, Nonsense Mutation 4, 5'UTR 2, 5'Flank 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 70/502 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 75/447 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61684095, COSV61696676; called by muse, mutect2, varscan2
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 212/1255 reads (17%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs368706037; called by muse, mutect2, varscan2
- ACVR2A | c.1304A>T p.K435I | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54027870; called by mutect2, varscan2
- ADGRV1 | c.10765C>T p.P3589S | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV67983066; called by mutect2, varscan2
- ANKRD30BL | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 82/623 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs1416249576; called by muse, mutect2, varscan2
- BDNF | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 124/1089 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59233695; called by muse, mutect2, varscan2
- CDH4 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 67/701 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs1005735675, COSV64663856; called by muse, mutect2
- CLDN8 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1364482689; called by muse, mutect2
- CPNE4 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 37/435 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370033923; called by muse, mutect2
- CTNND2 | c.3188G>A p.R1063H | Missense Mutation (SNP) | VAF 131/877 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs113076343, COSV58908332, COSV58933321; called by muse, mutect2, varscan2
- DNAH5 | c.8138G>A p.R2713H | Missense Mutation (SNP) | VAF 96/877 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150536659; called by muse, mutect2, varscan2
- FMN2 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs967255135; called by muse, mutect2, varscan2
- LMOD2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 35/348 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV71755639; called by muse, mutect2
- METTL9 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 35/828 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV63961146; called by muse, mutect2
- MSC | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as COSV57696776, COSV57697167; called by muse, mutect2, varscan2
- NEUROG3 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 116/1133 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV54342438; called by muse, mutect2
- NGF | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 133/857 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.057); catalogued as rs201087374; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R12C | c.1754C>G p.A585G | Missense Mutation (SNP) | VAF 99/662 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54738802; called by muse, mutect2, varscan2
- PRAMEF20 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 230/1704 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as rs1234445065; called by muse, varscan2
- PRRG3 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 44/138 reads (32%) | catalogued as rs765253591; called by muse, mutect2, varscan2
- SBK1 | c.1153G>A p.V385M | Missense Mutation (SNP) | VAF 142/1004 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.014); catalogued as rs1192791653; called by muse, mutect2, varscan2
- SCN4A | c.3788C>T p.P1263L | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs767272792; called by muse, mutect2, varscan2
- SLC45A4 | c.1834C>G p.P612A (on ENST00000517878 / NM_001286646.2; = p.P561A on NM_001080431.2) | Missense Mutation (SNP) | VAF 45/1458 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV50139951; called by muse, mutect2
- SMC1B | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs754559505; called by muse, mutect2, varscan2
- SPATA19 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs139528428, COSV54483539; called by muse, mutect2
- SV2A | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782011566, COSV100975223; called by muse, mutect2, varscan2
- TAT | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 42/1086 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV63532476, COSV63533271; called by muse, mutect2
- TENM3 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 57/401 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs766457503, COSV69313834; called by muse, mutect2, varscan2
- U2AF2 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV50038179; called by muse, mutect2, varscan2
- VCAN | c.7034C>T p.T2345M | Missense Mutation (SNP) | VAF 99/881 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs765414121, COSV54116413; called by muse, mutect2, varscan2
- ZNF135 | c.1036C>T p.R346* (on ENST00000313434 / NM_001289401.2; = p.R358* on NM_003436.4) | Nonsense Mutation (SNP) | VAF 172/843 reads (20%) | catalogued as rs144688815, COSV100536601; called by muse, mutect2, varscan2
- ZSCAN5C | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs755102345, COSV66186015; called by muse, mutect2
- A2ML1 | c.2680A>T p.S894C | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- C12orf65 | c.282+4G>T | Splice Region (SNP) | VAF 31/272 reads (11%) | called by muse, mutect2, varscan2
- ELAVL3 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GALC | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2
- GALR2 | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 112/881 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KREMEN1 | c.220G>A p.G74R (on ENST00000407188; = p.G76R on NM_032045.5) | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTSS2 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MUC4 | c.15910G>A p.G5304S (on ENST00000463781 / NM_018406.7; = p.G1068S on NM_004532.6) | Missense Mutation (SNP) | VAF 55/482 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MUC5B | c.692T>A p.F231Y | Missense Mutation (SNP) | VAF 42/410 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PACRGL | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2
- SLC45A4 | c.1257C>A p.F419L (on ENST00000517878 / NM_001286646.2; = p.F368L on NM_001080431.2) | Missense Mutation (SNP) | VAF 18/548 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2
- SOBP | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 93/678 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- SPO11 | c.147del p.S50Lfs*2 | Frame Shift Del (DEL) | VAF 19/152 reads (13%) | called by mutect2, pindel, varscan2
- SST | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TENT5B | c.383T>A p.L128Q | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.23740C>A p.L7914I (on ENST00000591111; = p.L6987I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/264 reads (8%) | PolyPhen benign (0.013); called by muse, mutect2
- WAC | c.1223del p.T408Mfs*9 | Frame Shift Del (DEL) | VAF 36/315 reads (11%) | called by mutect2, pindel, varscan2
- ZIC3 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 74/271 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CD79A | c.384G>A p.P128= | Silent (SNP) | VAF 48/298 reads (16%) | catalogued as rs782014534, COSV99701945; called by muse, mutect2, varscan2
- CFAP161 | c.150C>G p.L50= | Silent (SNP) | VAF 7/161 reads (4%) | catalogued as COSV54428839; called by muse, mutect2
- CHRNA1 | c.843C>A p.P281= (on ENST00000261007 / NM_001039523.3; = p.P256= on NM_000079.4) | Silent (SNP) | VAF 119/841 reads (14%) | called by muse, mutect2, varscan2
- CNMD | c.51C>T p.D17= | Silent (SNP) | VAF 74/513 reads (14%) | catalogued as COSV65033036; called by muse, mutect2, varscan2
- DPP3 | c.873G>A p.E291= | Silent (SNP) | VAF 23/191 reads (12%) | called by muse, mutect2, varscan2
- GPR4 | c.42C>T p.R14= | Silent (SNP) | VAF 55/245 reads (22%) | catalogued as rs753692265; called by muse, mutect2, varscan2
- KEAP1 | c.735C>A p.V245= | Silent (SNP) | VAF 16/554 reads (3%) | called by muse, mutect2
- KIAA0513 | c.705G>A p.S235= | Silent (SNP) | VAF 72/512 reads (14%) | catalogued as rs148794095; called by muse, mutect2, varscan2
- KLHDC8A | c.306C>T p.I102= | Silent (SNP) | VAF 26/262 reads (10%) | called by muse, mutect2, varscan2
- LCP2 | c.426C>T p.D142= | Silent (SNP) | VAF 46/313 reads (15%) | catalogued as rs561432915, COSV50450599; called by muse, mutect2, varscan2
- MATN1 | c.396C>T p.F132= | Silent (SNP) | VAF 32/318 reads (10%) | catalogued as rs369857270; called by muse, mutect2
- MRGPRX3 | c.210G>A p.A70= | Silent (SNP) | VAF 35/311 reads (11%) | catalogued as rs749919475, COSV66934205; called by muse, mutect2, varscan2
- MUC16 | c.31977G>A p.S10659= | Silent (SNP) | VAF 59/328 reads (18%) | catalogued as rs369258964, COSV67495078; called by muse, mutect2, varscan2
- NYAP2 | c.660G>A p.T220= | Silent (SNP) | VAF 41/395 reads (10%) | catalogued as rs752905382, COSV56003551; called by muse, mutect2, varscan2
- PAAF1 | c.15G>A p.L5= | Silent (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- PCDHA13 | c.1233C>T p.S411= | Silent (SNP) | VAF 104/731 reads (14%) | called by muse, mutect2, varscan2
- PDZRN4 | c.243C>T p.C81= | Silent (SNP) | VAF 93/629 reads (15%) | catalogued as COSV68413605; called by muse, mutect2, varscan2
- PIM3 | c.639G>T p.P213= | Silent (SNP) | VAF 59/292 reads (20%) | called by muse, mutect2, varscan2
- POU6F2 | c.165C>T p.S55= | Silent (SNP) | VAF 42/266 reads (16%) | catalogued as rs192309744, COSV101302775, COSV101302905; called by muse, mutect2, varscan2
- RIMS1 | c.3871C>A p.R1291= | Silent (SNP) | VAF 20/282 reads (7%) | catalogued as COSV53454539; called by muse, mutect2
- SLITRK2 | c.2397T>C p.N799= | Silent (SNP) | VAF 52/197 reads (26%) | called by muse, mutect2, varscan2
- TP63 | c.1890C>T p.S630= | Silent (SNP) | VAF 47/451 reads (10%) | called by muse, mutect2, varscan2
- UBQLN3 | c.537T>A p.G179= | Silent (SNP) | VAF 58/398 reads (15%) | called by muse, mutect2, varscan2
- ZMYM6 | c.174T>G p.P58= | Silent (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- CD81 | c.67-4267G>T | Intron (SNP) | VAF 68/562 reads (12%) | catalogued as rs1437518025; called by muse, mutect2, varscan2
- DZANK1 | c.379-77A>C | Intron (SNP) | VAF 53/428 reads (12%) | called by muse, mutect2, varscan2
- FNTA | c.-4C>T | 5'UTR (SNP) | VAF 77/236 reads (33%) | called by muse, mutect2, varscan2
- KMT5C | c.570+980G>A | Intron (SNP) | VAF 209/1058 reads (20%) | called by muse, mutect2, varscan2
- LRP1 | c.10594+10G>C | Intron (SNP) | VAF 13/324 reads (4%) | called by muse, mutect2
- RIMS2 | c.698+52954A>G | Intron (SNP) | VAF 48/442 reads (11%) | catalogued as rs572378309, COSV51655429; called by mutect2, varscan2
- RN7SKP78 | chr10:6144970 C>T | 5'Flank (SNP) | VAF 25/90 reads (28%) | called by muse, mutect2, varscan2
- SEC63 | c.1935+34C>G | Intron (SNP) | VAF 16/346 reads (5%) | called by muse, mutect2
- TAPBP | c.-1C>T | 5'UTR (SNP) | VAF 79/600 reads (13%) | catalogued as rs1190044667; called by muse, mutect2, varscan2
- ZC2HC1C | chr14:75069175 G>T | 5'Flank (SNP) | VAF 28/738 reads (4%) | called by muse, mutect2
